Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8531, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8531-01A (Primary Tumor).

[page 1 of 5]
HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain; constipation; fever; vomit

Symptoms: weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)		
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY	
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses 13 years old Date of Last Menses 52 years old
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other: _____	
☐ Hormone Replacement Therapy: _____	

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the stomach	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
STOMACH CANCER	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T 3 N 1 M 0	Stage: III A

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Extended Gastrectomy		
Primary Tumor		
Organ	Detailed Location	Size
Stomach tumor	lesser curvatures	6 x 5 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 3 N 1 M 0 Stage: III A		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	6 x 5 x 2 cm	lesser curvatures	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	

Pathological Staging	
pT 3 N 1 M 0	Stage: IIA

Notes:	M ₁ (+) M ₂ (+) positive stomach metast nodes 7 (positive 2, negative 5)
--------	--

[page 5 of 5]
1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse		X		Streaming			
Mosaic			X	Storiform			
Necrosis			X	Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized			X	Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psamomma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification		X	Fibroblast			Small Cell		
Keratin			Secretion		X	Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation		X	Myoblast			Plasma Cell		
Otherwise Specified: D ₁ 75% D ₂ 75% D ₃ 75% D ₄ 75%											

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				X
Hyperchromatism				X
Nucleolar Prominent				X
Multinucleated Giant Cell				X
Mitotic Activity				X
Nuclear Grade				X

Histological Diagnosis: Diffuse poorly differentiated Adenocarcinoma

Comments: M₁, M₂: Carcinoma metastasized to 3

Source: NCI Genomic Data Commons file d145d153-6f20-472f-9c14-6209fa93cb88 (TCGA-CD-8531.A2926F17-34EA-4E19-BB94-9B894534AE9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).